Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3664, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3664-01A (Primary Tumor).

Diagnosis/ diagnoses:

Right hemicolectomy preparation with an ulcerated colon carcinoma characterized histologically as a moderately differentiated colorectal adenocarcinoma, located at the junction between the cecum and the ascending colon, extending to Bauhin's valve and measuring 5 cm in diameter at the widest point. Invasive tumor spread to the adjoining mesocolic fatty tissue and beneath the serosa.

Oral and aboral resection margins, appendix and greater omentum are all tumor-free.

22 mesenteric and mesocolic lymph nodes are tumor-free and with uncharacteristic reactive changes.

Stage of tumor is therefore: pT3 pN0 (0/22); L0 V0; G2

Source: NCI Genomic Data Commons file 40425db0-ff6f-4db9-a188-99c4c153ab2f (TCGA-AA-3664.C000F50B-58B6-4C7A-9859-43D199747CF0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).